RC case RC-B6SS — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Connective, subcutaneous and other soft tissues. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ec9d0b3e-a07d-4d8e-bd5c-9aa763b2818a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1969; Vital status: Alive; Country of birth: United States.

Diagnoses (2)
1. Anaplastic large cell lymphoma, T cell and Null cell type (the primary disease): ICD-O-3 morphology code: 9714/3; ICD-10 code: C84; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Site of resection or biopsy: Lymph nodes of inguinal region or leg; Classification of tumor: primary; Age at diagnosis: 50.7 years (18,503 days); Year of diagnosis: 2019; Method of diagnosis: Core Biopsy; Ann Arbor B symptoms: Yes; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: Yes; Ann arbor b symptoms described array: Weight Loss / Night Sweats; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High Risk; Sites of involvement: Lymph Node, Mediastinal / Lymph Node, Mesenteric / Bone, NOS / Mediastinal soft tissue / Small intestine.
   Pathology details: Bone marrow malignant cells: No; Greatest tumor dimension: 2.4 cm; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Brentuximab Vedotin + Cyclophosphamide + Doxorubicin + Prednisone; Initial disease status: Initial Diagnosis; Regimen or line of therapy: BV-CHP; Days to treatment start: 1 day; Days to treatment end: 105 days; Number of cycles: 6; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Hodgkin lymphoma, NOS: ICD-O-3 morphology code: 9650/3; Tissue or organ of origin: Lymph node, NOS; Laterality: Bilateral; Classification of tumor: Prior primary; Age at diagnosis: 34.2 years (12,503 days); Year of diagnosis: 2003; Days to diagnosis: -6,000 days (-16.4 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Bleomycin + Doxorubicin + Etoposide + Mechlorethamine + Prednisone + Vinblastine + Vincristine; Days to treatment start: -5,996 days (-16.4 years); Treatment anatomic sites: Body, total.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Surgery, NOS.

Follow-up (3 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 80.
- Day 63 (end of treatment course 1): Disease response: Tumor Free; Imaging type: PET; Imaging result: Negative.
- Day 1,085 (within 2 months after completion of first-course treatment): Disease response: Tumor Free; Imaging type: PET; Imaging result: Negative.

Molecular and laboratory tests
- Epstein-Barr Virus (ISH): Negative.
- Lactate Dehydrogenase 4870 U/L [Blood test normal range upper: 250].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Hodgkin Lymphoma.
- Timepoint category: Initial Diagnosis; Weight: 82 kg; Height: 177 cm; BMI: 26.2.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Cancer.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Colorectal Cancer.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B6SS-NB1-A: Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample RC-B6SS-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide RC-B6SS-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 65; Percent normal cells: 25; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 3.
